Somatic mutation profile of tumor specimen 0DCYQ4 from CCDI case PBBNAY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.1 years (2,222 days).
Specimen 0DCYQ4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 306da253-2773-4bb4-aa9f-247eaef5ea7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCYQ3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1444db7b-c101-4fad-9a0a-837701f56354

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HNRNPU | c.1925-9_1925-5del | Splice Region (DEL) | VAF 153/362 reads (42%) | catalogued as rs1558186076; called by mutect2, varscan2
- MYOM2 | c.925C>T p.R309W | Missense Mutation (SNP) | VAF 26/636 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs564805058; called by muse, mutect2
- RAD21 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 300/669 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52055974; called by muse, mutect2, varscan2
- RIPOR3 | c.1639C>T p.R547W | Missense Mutation (SNP) | VAF 255/613 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs1011101381; called by muse, mutect2, varscan2
- TAFA1 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 271/569 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs550621255, COSV72040343; called by muse, mutect2, varscan2
- CDC14C | c.1176A>T p.K392N (on ENST00000428251; = p.K285N on NM_152627.3) | Missense Mutation (SNP) | VAF 175/1076 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- MYO7A | c.3960G>T p.M1320I | Missense Mutation (SNP) | VAF 119/541 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP3CB | c.982+1G>T p.X328_splice | Splice Site (SNP) | VAF 148/152 reads (97%) | called by muse, mutect2, varscan2
- CSTF2T | c.1251G>A p.A417= | Silent (SNP) | VAF 514/1017 reads (51%) | catalogued as COSV58657747; called by muse, mutect2, varscan2
- FSIP2 | c.14769T>C p.V4923= | Silent (SNP) | VAF 123/732 reads (17%) | catalogued as rs749093355; called by muse, mutect2, varscan2
- SCUBE1 | c.663C>T p.D221= | Silent (SNP) | VAF 283/651 reads (43%) | called by muse, mutect2, varscan2
